Somatic mutation profile of tumor specimen TCGA-CC-A5UE-01A (aliquot TCGA-CC-A5UE-01A-11D-A28X-10) from TCGA case TCGA-CC-A5UE, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 48.7 years (17,805 days).
Specimen TCGA-CC-A5UE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 96fda110-d132-4dbb-b0af-81299b82c8f6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CC-A5UE-10A (Blood Derived Normal), aliquot TCGA-CC-A5UE-10A-01D-A28X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f51f8506-804f-459c-b1a1-e788621dc29a

The open-access MAF lists 141 somatic variants for this specimen: 111 protein-altering or splice-affecting, 27 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 94, Silent 27, Nonsense Mutation 6, Frame Shift Del 4, Frame Shift Ins 3, Translation Start Site 1, RNA 1, Intron 1, Splice Site 1, 3'UTR 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAD11 | c.13G>T p.A5S | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.197); catalogued as COSV53894061; called by muse, mutect2, varscan2
- ADAMTS1 | c.272C>A p.P91H | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as COSV53168941; called by muse, mutect2, varscan2
- AL049569.3 | c.247G>T p.A83S | Missense Mutation (SNP) | VAF 32/178 reads (18%) | catalogued as COSV58698488; called by muse, mutect2, varscan2
- ASTL | c.592G>T p.D198Y | Missense Mutation (SNP) | VAF 98/201 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753572086, COSV60903643, COSV60905564; called by muse, mutect2, varscan2
- AZIN1 | c.927A>T p.E309D | Missense Mutation (SNP) | VAF 82/120 reads (68%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV61479316; called by muse, mutect2, varscan2
- BRSK2 | c.936C>A p.F312L | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV57540290, COSV57540594; called by muse, varscan2
- CCNT1 | c.679G>T p.A227S | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0.009); catalogued as COSV56063408; called by muse, mutect2, varscan2
- CDC42EP1 | c.957G>T p.R319S | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.122); catalogued as COSV50755700; called by muse, mutect2, varscan2
- CELSR1 | c.815C>A p.T272N | Missense Mutation (SNP) | VAF 36/65 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.247); catalogued as COSV99417822; called by muse, varscan2
- CHST3 | c.30C>A p.D10E | Missense Mutation (SNP) | VAF 44/58 reads (76%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.001); catalogued as COSV64150555; called by muse, mutect2, varscan2
- COL11A1 | c.1594G>C p.G532R | Missense Mutation (SNP) | VAF 138/190 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100616848, COSV62174716, COSV62185632; called by muse, mutect2, varscan2
- CRHR1 | c.4G>T p.G2* | Nonsense Mutation (SNP) | VAF 13/26 reads (50%) | catalogued as COSV53275971; called by muse, mutect2, varscan2
- CRHR2 | c.173C>A p.A58D | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.07); catalogued as rs756090500, COSV59263986; called by muse, mutect2, varscan2
- CTLA4 | c.61C>A p.P21T | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.146); catalogued as COSV55591859, COSV55593291; called by muse, mutect2, varscan2
- DCC | c.2785A>T p.S929C | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59087627; called by muse, mutect2, varscan2
- DDI1 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56370050, COSV56390070; called by muse, mutect2, varscan2
- DDX60L | c.4054C>G p.L1352V | Missense Mutation (SNP) | VAF 158/322 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV52709826; called by muse, mutect2, varscan2
- DOCK2 | c.2632C>A p.Q878K | Missense Mutation (SNP) | VAF 55/125 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.037); catalogued as COSV56944913; called by muse, mutect2, varscan2
- EFEMP1 | c.356T>C p.V119A | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT tolerated (0.68); PolyPhen benign (0.021); catalogued as COSV62615206; called by muse, mutect2, varscan2
- EIF2AK2 | c.912G>T p.K304N | Missense Mutation (SNP) | VAF 55/99 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV51794990; called by muse, mutect2, varscan2
- ERC2 | c.2857G>C p.E953Q | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as COSV55604820; called by muse, mutect2, varscan2
- FAT3 | c.11197A>G p.M3733V | Missense Mutation (SNP) | VAF 68/151 reads (45%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs1303458972, COSV53081948; called by muse, mutect2, varscan2
- FBN1 | c.580A>T p.M194L | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.062); catalogued as COSV57310775; called by muse, mutect2, varscan2
- FGA | c.2226C>G p.F742L | Missense Mutation (SNP) | VAF 80/108 reads (74%) | SIFT tolerated (1); PolyPhen benign (0.291); catalogued as COSV57393530; called by muse, mutect2, varscan2
- GPSM1 | c.1399G>C p.E467Q | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.014); catalogued as COSV61303224; called by muse, mutect2, varscan2
- HAVCR1 | c.775A>T p.T259S | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT tolerated (0.85); PolyPhen benign (0.042); catalogued as COSV59398132; called by muse, mutect2, varscan2
- HIPK2 | c.2300A>T p.Q767L | Missense Mutation (SNP) | VAF 81/155 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV61226060; called by muse, mutect2, varscan2
- HNRNPC | c.859G>T p.E287* (on ENST00000420743; = p.E274* on NM_004500.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 26/64 reads (41%) | catalogued as COSV60143975; called by muse, mutect2, varscan2
- HNRNPH1 | c.1140C>A p.F380L | Missense Mutation (SNP) | VAF 59/172 reads (34%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.762); catalogued as COSV61484984; called by muse, mutect2, varscan2
- ICE1 | c.1840G>A p.D614N | Missense Mutation (SNP) | VAF 53/105 reads (50%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV56820118; called by muse, mutect2, varscan2
- ITGA3 | c.1006G>T p.E336* | Nonsense Mutation (SNP) | VAF 65/145 reads (45%) | catalogued as COSV50306408; called by muse, mutect2, varscan2
- JPH3 | c.448T>C p.Y150H | Missense Mutation (SNP) | VAF 30/42 reads (71%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV52464811; called by muse, varscan2
- KMT2A | c.9838C>T p.R3280* | Nonsense Mutation (SNP) | VAF 27/63 reads (43%) | catalogued as COSV63282766; called by muse, mutect2, varscan2
- LAPTM5 | c.664G>T p.V222L | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV53852531; called by muse, mutect2, varscan2
- LCK | c.622C>A p.H208N | Missense Mutation (SNP) | VAF 106/144 reads (74%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100287618; called by muse, mutect2, varscan2
- LCT | c.937G>A p.G313R | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51544885, COSV51548702; called by muse, mutect2, varscan2
- LMBRD2 | c.655A>T p.R219W | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.75); catalogued as COSV56948882; called by muse, mutect2, varscan2
- LMOD3 | c.1620C>A p.N540K | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.258); catalogued as rs753299503, COSV70455721; called by muse, mutect2, varscan2
- LOXL4 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs377758453; called by muse, mutect2, varscan2
- LRCH3 | c.1184G>A p.G395E | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.036); catalogued as rs773998276, COSV58389632; called by muse, mutect2, varscan2
- LRRC45 | c.1905G>C p.E635D | Missense Mutation (SNP) | VAF 44/65 reads (68%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV60710507; called by muse, mutect2, varscan2
- LRRK2 | c.1597G>T p.V533F | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.101); catalogued as COSV54145789; called by muse, mutect2, varscan2
- LTBP1 | c.4140G>T p.W1380C (on ENST00000404816 / NM_206943.4; = p.W1054C on NM_000627.4) | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55376140; called by muse, mutect2, varscan2
- LTBP2 | c.1732G>T p.G578C | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV56205655; called by muse, mutect2, varscan2
- LYSMD4 | c.827T>A p.V276D (on ENST00000409796 / NM_001284417.2; = p.V277D on NM_152449.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/128 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as COSV60386040; called by muse, mutect2, varscan2
- MED13 | c.6364G>C p.D2122H | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67262191; called by muse, mutect2, varscan2
- MEIS2 | c.1320G>T p.M440I | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.675); catalogued as COSV54931965; called by muse, mutect2, varscan2
- METTL2B | c.766A>G p.I256V | Missense Mutation (SNP) | VAF 78/124 reads (63%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs1343043459, COSV52307944; called by muse, mutect2, varscan2
- MGARP | c.665G>T p.G222V | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); catalogued as COSV67449066; called by muse, mutect2, varscan2
- MPPED2 | c.785C>A p.S262Y | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV71560691; called by muse, mutect2, varscan2
- MYO1B | c.2747G>C p.R916T (on ENST00000304164; = p.R858T on NM_012223.5) | Missense Mutation (SNP) | VAF 44/91 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.071); catalogued as COSV58427840; called by muse, mutect2, varscan2
- NEFH | c.3047C>A p.A1016D | Missense Mutation (SNP) | VAF 37/61 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.663); catalogued as COSV60215493; called by muse, mutect2, varscan2
- NEK10 | c.845A>T p.Q282L | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.059); catalogued as COSV58280602; called by muse, mutect2, varscan2
- NEUROD6 | c.52T>A p.C18S | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT tolerated (0.43); PolyPhen benign (0.062); catalogued as COSV51770292; called by muse, mutect2, varscan2
- NKIRAS2 | c.275A>G p.E92G | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as rs1555653325, COSV56917470; called by muse, mutect2, varscan2
- NOLC1 | c.1783G>T p.A595S | Missense Mutation (SNP) | VAF 30/40 reads (75%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.045); catalogued as COSV64180024; called by muse, mutect2, varscan2
- NPEPL1 | c.1002G>A p.K334= | Splice Region (SNP) | VAF 50/117 reads (43%) | catalogued as COSV61938214; called by muse, mutect2, varscan2
- NTNG2 | c.1371C>A p.D457E | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV62364910; called by muse, mutect2, varscan2
- OR2D3 | c.985A>T p.R329W | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV53491916; called by muse, mutect2, varscan2
- OR2T27 | c.434T>C p.V145A | Missense Mutation (SNP) | VAF 91/176 reads (52%) | SIFT tolerated (0.63); PolyPhen benign (0.023); catalogued as COSV61280995, COSV61282877; called by muse, mutect2, varscan2
- PARD3B | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.856); catalogued as COSV62504258; called by muse, mutect2, varscan2
- PCDH12 | c.263C>G p.T88R | Missense Mutation (SNP) | VAF 93/181 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51519757; called by muse, mutect2, varscan2
- PDX1 | c.527G>T p.R176L | Missense Mutation (SNP) | VAF 36/43 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM130466, COSV66846954; called by muse, mutect2, varscan2
- PECR | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 42/77 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.954); catalogued as COSV54733580, COSV54733615; called by muse, mutect2, varscan2
- PGR | c.2219G>A p.R740Q | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs149186732; called by muse, mutect2, varscan2
- PIKFYVE | c.418G>C p.E140Q | Missense Mutation (SNP) | VAF 60/115 reads (52%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV52237740; called by muse, mutect2, varscan2
- PKHD1 | c.1783G>T p.V595F | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); catalogued as COSV61863143; called by muse, mutect2, varscan2
- PLD3 | c.33G>T p.K11N | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.95); catalogued as COSV62924210; called by muse, mutect2, varscan2
- PPP2R1A | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV59042740; called by muse, mutect2, varscan2
- PREX1 | c.590A>T p.Q197L | Missense Mutation (SNP) | VAF 56/121 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64248446; called by muse, mutect2, varscan2
- PRSS45P | c.604G>A p.G202R | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1366040869, COSV70576885; called by muse, mutect2, varscan2
- PTGR1 | c.770del p.P257Qfs*28 | Frame Shift Del (DEL) | VAF 10/55 reads (18%) | catalogued as COSV53030433, COSV99437253; called by mutect2, pindel, varscan2
- RAG1 | c.634G>T p.D212Y | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.718); catalogued as COSV55024083; called by muse, mutect2, varscan2
- RHBDL3 | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 79/182 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52184780; called by muse, mutect2, varscan2
- ROBO4 | c.988G>T p.A330S | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.531); catalogued as COSV60621855; called by muse, mutect2, varscan2
- RTF1 | c.1079A>G p.N360S | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.968); catalogued as COSV67477790; called by muse, mutect2, varscan2
- RTL4 | c.184A>T p.T62S | Missense Mutation (SNP) | VAF 119/265 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV61205678; called by muse, mutect2, varscan2
- RYR2 | c.9026G>T p.C3009F | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100768286, COSV63666481; called by muse, mutect2, varscan2
- SDCCAG8 | c.328A>G p.T110A | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs1448996546, COSV100654611, COSV59405332; called by muse, mutect2, varscan2
- SFXN2 | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 19/23 reads (83%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.718); catalogued as COSV64011875; called by muse, mutect2, varscan2
- SLC4A3 | c.1868G>T p.R623L | Missense Mutation (SNP) | VAF 105/224 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1489059788, COSV56091943; called by muse, mutect2, varscan2
- SMARCA4 | c.356-2A>T p.X119_splice | Splice Site (SNP) | VAF 24/32 reads (75%) | catalogued as COSV60788317; called by muse, mutect2, varscan2
- SND1 | c.1969G>C p.V657L | Missense Mutation (SNP) | VAF 48/83 reads (58%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV61236039; called by muse, mutect2, varscan2
- SOGA1 | c.2726T>C p.F909S | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); catalogued as COSV52912768; called by muse, mutect2, varscan2
- SOS1 | c.3176A>G p.E1059G | Missense Mutation (SNP) | VAF 67/130 reads (52%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.928); catalogued as rs767619216, COSV67674059; called by muse, mutect2, varscan2
- SPAST | c.261G>A p.M87I | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.541); catalogued as COSV59513019; called by muse, mutect2
- TAF1 | c.4727T>C p.I1576T (on ENST00000373790 / NM_138923.4; = p.I1597T on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/73 reads (86%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); catalogued as COSV52108415; called by muse, mutect2, varscan2
- TGFBRAP1 | c.2050C>T p.H684Y | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.393); catalogued as COSV51510249; called by muse, mutect2, varscan2
- TH | c.455C>T p.P152L (on ENST00000381178 / NM_199292.3; = p.P121L on NM_000360.4) | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs760017478, COSV60766775; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- THSD7B | c.1870G>A p.G624R | Missense Mutation (SNP) | VAF 47/144 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55660088; called by muse, mutect2, varscan2
- TMEM132A | c.936G>T p.K312N | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV50001781; called by mutect2, varscan2
- TSHZ2 | c.2918G>T p.R973L | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as CM142650, COSV61587217, COSV61587698; called by muse, mutect2, varscan2
- TUSC3 | c.7G>T p.A3S | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs764280802, COSV65878277; called by muse, mutect2, varscan2
- USH1C | c.556G>A p.D186N | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as COSV50014313; called by muse, mutect2, varscan2
- USH1G | c.721G>T p.A241S | Missense Mutation (SNP) | VAF 27/34 reads (79%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs756539436, COSV58880848; called by muse, mutect2, varscan2
- USP26 | c.2459G>T p.G820V | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.898); catalogued as COSV63708178, COSV63708333; called by muse, mutect2, varscan2
- USP9Y | c.5425G>T p.E1809* | Nonsense Mutation (SNP) | VAF 25/32 reads (78%) | catalogued as COSV59098824; called by muse, mutect2, varscan2
- VASP | c.334G>T p.A112S | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV55606042; called by muse, mutect2, varscan2
- WFDC3 | c.686C>T p.P229L | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as rs1424144931, COSV54784481; called by muse, mutect2, varscan2
- XKR4 | c.706G>T p.A236S | Missense Mutation (SNP) | VAF 57/128 reads (45%) | SIFT tolerated (0.55); PolyPhen benign (0.053); catalogued as COSV59301800; called by muse, mutect2, varscan2
- ZDHHC4 | c.61A>G p.I21V | Missense Mutation (SNP) | VAF 81/152 reads (53%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV60106037; called by muse, mutect2, varscan2
- ZFP37 | c.201C>A p.N67K | Missense Mutation (SNP) | VAF 64/110 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as rs1247872334, COSV65286009; called by muse, mutect2, varscan2
- ZNF223 | c.1051A>G p.K351E | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV71571793; called by muse, mutect2, varscan2
- ZNF534 | c.943G>T p.E315* (on ENST00000332323 / NM_001143939.3; = p.E302* on NM_001143938.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 24/81 reads (30%) | catalogued as COSV56514882; called by muse, mutect2, varscan2
- ALB | c.185_188dup p.H63Qfs*8 | Frame Shift Ins (INS) | VAF 27/40 reads (68%) | called by mutect2, pindel, varscan2
- AXIN1 | c.1409dup p.L471Pfs*120 | Frame Shift Ins (INS) | VAF 13/23 reads (57%) | called by mutect2, pindel, varscan2
- COL15A1 | c.2337_2338insT p.M780Yfs*24 | Frame Shift Ins (INS) | VAF 7/43 reads (16%) | called by mutect2, pindel, varscan2
- DENND2B | c.390del p.C131Afs*22 | Frame Shift Del (DEL) | VAF 10/23 reads (43%) | called by mutect2, pindel, varscan2
- HNRNPUL1 | c.1599del p.T534Lfs*5 | Frame Shift Del (DEL) | VAF 28/58 reads (48%) | called by mutect2, varscan2
- KCNJ4 | c.761_769del p.F254_V256del | In Frame Del (DEL) | VAF 33/143 reads (23%) | called by mutect2, pindel, varscan2
- RANBP2 | c.1820_1821delinsT p.K607Ifs*7 | Frame Shift Del (DEL) | VAF 61/566 reads (11%) | called by pindel, varscan2*
- ADGRA2 | c.1945C>A p.R649= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as rs898277851, COSV59441271; called by muse, mutect2, varscan2
- AFAP1L2 | c.1539T>G p.A513= | Silent (SNP) | VAF 25/32 reads (78%) | catalogued as COSV58412655; called by muse, mutect2, varscan2
- C7orf25 | c.1089G>A p.G363= | Silent (SNP) | VAF 72/122 reads (59%) | catalogued as COSV63273208; called by muse, mutect2, varscan2
- CADPS2 | c.657A>G p.K219= | Silent (SNP) | VAF 58/92 reads (63%) | catalogued as COSV57351650; called by muse, mutect2, varscan2
- CAMK1D | c.792G>A p.P264= | Silent (SNP) | VAF 20/233 reads (9%) | catalogued as rs199768578, COSV66607544; called by muse, mutect2
- CTTNBP2 | c.4821A>T p.S1607= | Silent (SNP) | VAF 21/38 reads (55%) | catalogued as COSV50390782; called by muse, mutect2, varscan2
- DIP2A | c.1227G>T p.V409= | Silent (SNP) | VAF 72/117 reads (62%) | catalogued as rs753316767, COSV59473212; called by muse, mutect2, varscan2
- FBXO31 | c.1578C>T p.A526= | Silent (SNP) | VAF 43/55 reads (78%) | catalogued as COSV61147879; called by muse, varscan2
- GCKR | c.1557G>T p.A519= | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as COSV53106741; called by muse, mutect2, varscan2
- GPR149 | c.531C>T p.R177= | Silent (SNP) | VAF 18/30 reads (60%) | catalogued as COSV67666048, COSV67669208; called by muse, mutect2, varscan2
- HECTD3 | c.2379G>A p.T793= | Silent (SNP) | VAF 49/170 reads (29%) | catalogued as rs373641285; called by muse, mutect2, varscan2
- HERC2 | c.888G>T p.L296= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as COSV55310617; called by muse, mutect2, varscan2
- LCK | c.621C>A p.R207= | Silent (SNP) | VAF 106/144 reads (74%) | catalogued as COSV100287614; called by muse, mutect2, varscan2
- LRCH4 | c.1300T>C p.L434= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as rs936424178, COSV59642332; called by muse, mutect2, varscan2
- MMP21 | c.1569C>T p.G523= | Silent (SNP) | VAF 39/53 reads (74%) | catalogued as COSV61762614; called by muse, mutect2, varscan2
- MYH10 | c.4827G>A p.R1609= | Silent (SNP) | VAF 27/37 reads (73%) | catalogued as COSV52595882; called by muse, mutect2, varscan2
- NRXN1 | c.3499C>A p.R1167= | Silent (SNP) | VAF 61/141 reads (43%) | catalogued as COSV58438923, COSV58455553; called by muse, mutect2, varscan2
- OR1B1 | c.9C>T p.S3= | Silent (SNP) | VAF 36/86 reads (42%) | catalogued as COSV59171278; called by muse, mutect2, varscan2
- OTULINL | c.210G>T p.G70= | Silent (SNP) | VAF 22/51 reads (43%) | catalogued as COSV57033708, COSV57035193; called by muse, mutect2, varscan2
- SCARA5 | c.393G>T p.A131= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV57275836; called by muse, mutect2, varscan2
- SEC16B | c.522G>A p.E174= | Silent (SNP) | VAF 77/105 reads (73%) | catalogued as COSV57623851; called by muse, mutect2, varscan2
- SEMA5A | c.2259G>A p.R753= | Silent (SNP) | VAF 44/143 reads (31%) | catalogued as COSV66785853; called by muse, mutect2, varscan2
- TBXAS1 | c.615T>A p.P205= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV54941182; called by muse, mutect2, varscan2
- TLR1 | c.1794C>T p.T598= | Silent (SNP) | VAF 64/110 reads (58%) | catalogued as COSV58303308; called by muse, mutect2, varscan2
- TPRN | c.1713C>T p.S571= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as COSV58806499; called by muse, mutect2, varscan2
- TTN | c.51625C>T p.L17209= (on ENST00000591111; = p.L9785= on NM_003319.4) | Silent (SNP) | VAF 47/103 reads (46%) | catalogued as rs773730675, COSV59884368, COSV59913188; called by muse, mutect2, varscan2
- TTN | c.415C>A p.R139= | Silent (SNP) | VAF 49/124 reads (40%) | catalogued as rs752970602, COSV59913211, COSV60149531; called by muse, mutect2, varscan2
- ISCA1P1 | n.165G>A | RNA (SNP) | VAF 80/185 reads (43%) | called by muse, varscan2
- TRPM3 | c.184-256777T>A | Intron (SNP) | VAF 34/65 reads (52%) | catalogued as COSV62660491; called by muse, mutect2, varscan2
- ZNF99 | c.*977C>T | 3'UTR (SNP) | VAF 14/30 reads (47%) | catalogued as rs540429316, COSV101233798; called by muse, mutect2, varscan2
